Gene-level copy-number profile of tumor specimen ALCH-B1MP-TTP1-A from ALCHEMIST case ALCH-B1MP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 80.0 years (29,223 days).
Specimen ALCH-B1MP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1bbe0277-be38-4a22-8472-2b8d8ad15f86.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1MP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/5b704aea-3759-4504-8c49-24c9533ec65d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 115; copy number 1: 195; copy number 2: 31,438; copy number 3: 12,631; copy number 4: 10,994; copy number 5: 427; copy number 6: 2,435; copy number 7: 164; copy number 9: 1; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 115 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,720,312–15,749,896, 4 genes (within-gene range 0–4): AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82.
- chr2:219,434,843–219,571,859, 13 genes (within-gene range 0–2): SPEG, ASIC4-AS1, AC053503.6, SPEGNB, AC053503.4, GMPPA, ASIC4, CHPF, TMEM198, AC009955.3, MIR3132, OBSL1, AC009955.4.
- chr7:43,940,895–44,042,306, 10 genes (within-gene range 0–2): POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP, LINC00957.
- chr7:44,051,766–44,051,829, 1 gene (within-gene range 0–2): MIR6837.
- chr8:7,955,014–8,226,614, 18 genes: FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:61,190,003–61,666,386, 12 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr9:114,323,056–114,394,405, 3 genes: ORM1, ORM2, AKNA.
- chr10:11,395,808–11,398,792, 1 gene: AC026887.1.
- chr11:62,662,817–62,673,686, 4 genes (within-gene range 0–3): LBHD1, CSKMT, SNORA57, UQCC3.
- chr13:63,783,801–64,076,044, 6 genes: RNU6-81P, PPP1R2P10, OR7E104P, AL445238.1, LINC00355, NFYAP1.
- chr13:80,697,177–81,691,072, 9 genes: AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5.
- chr16:32,388,135–32,436,203, 1 gene: AC138915.2.
- chr16:32,600,299–32,622,184, 2 genes: AC137800.1, AC137800.2.
- chr17:142,789–445,939, 10 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB.
- chr18:11,618,208–11,644,824, 4 genes: AP001120.4, NPIPB1P, AP001120.2, AP001120.3.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–2): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:41,301,587–41,425,002, 10 genes (within-gene range 0–3): TGFB1, AC011462.5, CCDC97, AC011462.1, TMEM91, B9D2, AC011462.4, EXOSC5, BCKDHA, AC011462.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,028 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,508,537–3,857,396, 43 genes, copy number 5 (within-gene range 3–5): PANK4, HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B, MMEL1, MMEL1-AS1, TTC34, AC242022.2, AC242022.1, AL592464.2, AL592464.3, AL592464.1, ACTRT2, PRDM16-DT, PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73, TP73, TP73-AS3, TP73-AS2, TP73-AS1, AL136528.1, CCDC27, SMIM1, LRRC47, RN7SL574P, AL365330.1, CEP104.
- chr1:202,331,657–202,592,706, 7 genes, copy number 6 (within-gene range 4–6): UBE2T, PPP1R12B, CYCSP4, RNU6-89P, AC099336.1, AC099336.2, SNORA70.
- chr3:93,843,764–198,123,232, 1,753 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–1,006,623, 38 genes, copy number 7: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2.
- chr5:1,252,006–45,895,970, 635 genes, copy number 6 (broad region; genes not listed).
- chr6:35,832,966–36,024,868, 3 genes, copy number 5 (within-gene range 4–5): SRPK1, SLC26A8, DPRXP2.
- chr7:76,071,469–76,132,187, 5 genes, copy number 5: AC005077.4, RNU6-863P, GTF2IP7, AC005077.2, AC005077.1.
- chr8:22,434,391–22,553,444, 4 genes, copy number 5 (within-gene range 2–5): RNU6-336P, PPP3CC, AC087854.1, BTF3P3.
- chr11:86,649–2,992,377, 161 genes, copy number 5 (broad region; genes not listed).
- chr11:72,814,406–73,181,724, 5 genes, copy number 5: ATG16L2, FCHSD2, RNU6-672P, AP002381.1, AP002761.2.
- chr11:120,236,640–120,319,945, 1 gene, copy number 5 (within-gene range 2–5): POU2F3.
- chr11:120,325,296–120,489,937, 3 genes, copy number 5: TLCD5, ARHGEF12, 7SK.
- chr12:120,762,510–120,904,358, 2 genes, copy number 5: SPPL3, ARF1P2.
- chr13:65,309,855–65,310,953, 1 gene, copy number 6: STARP1.
- chr13:89,991,831–90,135,841, 3 genes, copy number 6–9: PEX12P1, LINC00559, RNA5SP34.
- chr13:102,596,986–114,337,626, 167 genes, copy number 5–7 (broad region; genes not listed).
- chr14:21,990,496–22,531,998, 94 genes, copy number 5 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr16:32,439,069–32,441,159, 1 gene, copy number 10: PABPC1P13.
- chr20:62,544,343–63,891,545, 82 genes, copy number 5 (broad region; genes not listed).
- chr21:45,643,694–45,942,454, 4 genes, copy number 6 (within-gene range 3–6): PCBP3, AL133492.1, PCBP3-AS1, AJ011931.2.
- chr21:46,458,891–46,691,226, 7 genes, copy number 5: DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1, RPL23AP4.
- chr22:19,330,698–19,479,202, 8 genes, copy number 6: HIRA, C22orf39, RN7SL168P, MRPL40, AC000068.1, UFD1, AC000068.3, AC000068.2.

Autosomal genes at a single copy (total copy number 1): 195. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
